Somatic mutation profile of tumor specimen TARGET-30-PALXHW-01A (aliquot TARGET-30-PALXHW-01A-01W) from TARGET case TARGET-30-PALXHW, project TARGET-NBL (Neuroblastoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Neuroblastoma, NOS; Tissue or organ of origin: Medulla of adrenal gland; Age at diagnosis: 3.1 years (1,131 days).
Specimen TARGET-30-PALXHW-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5bf9625b-80ab-4674-a6ee-7f914e89d3b8.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-30-PALXHW-10A (Blood Derived Normal), aliquot TARGET-30-PALXHW-10A-01W; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/898d17b9-1dee-4ddc-bff9-75a3eb79d470

The open-access MAF lists 21 somatic variants for this specimen: 16 protein-altering or splice-affecting, 5 silent.
By variant classification: Missense Mutation 13, Silent 5, Splice Site 1, Nonsense Mutation 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DUSP16 | c.1447C>T p.R483* | Nonsense Mutation (SNP) | VAF 21/354 reads (6%) | hotspot (GDC flag); catalogued as COSV53806110; called by muse, mutect2
- ARID1A | c.5825G>A p.G1942D | Missense Mutation (SNP) | VAF 175/517 reads (34%) | SIFT tolerated (0.2); PolyPhen benign (0.08); catalogued as COSV61379343, COSV61388939; called by muse, mutect2, varscan2
- ATRX | c.6049T>C p.S2017P | Missense Mutation (SNP) | VAF 80/167 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV64877940; called by muse, mutect2, varscan2
- CCSER2 | c.2252G>T p.C751F | Missense Mutation (SNP) | VAF 22/69 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.777); catalogued as COSV56507598; called by muse, mutect2, varscan2
- EGR2 | c.214G>T p.D72Y | Missense Mutation (SNP) | VAF 119/302 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.754); catalogued as COSV54347198; called by muse, varscan2
- FGF18 | c.178C>T p.R60W | Missense Mutation (SNP) | VAF 20/221 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.861); catalogued as rs756441926, COSV51127441; called by muse, mutect2
- LAMC3 | c.2465G>T p.G822V | Missense Mutation (SNP) | VAF 33/106 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV63092935; called by muse, mutect2, varscan2
- LRIT2 | c.1327G>A p.G443S | Missense Mutation (SNP) | VAF 35/549 reads (6%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.952); catalogued as COSV100259296; called by muse, mutect2
- OR11G2 | c.701A>G p.E234G | Missense Mutation (SNP) | VAF 128/360 reads (36%) | SIFT deleterious (0.02); PolyPhen benign (0.208); catalogued as COSV62132653; called by muse, mutect2, varscan2
- OTOP2 | c.1239G>T p.Q413H | Missense Mutation (SNP) | VAF 25/123 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1237939240, COSV58882432; called by muse, mutect2, varscan2
- RGS11 | c.486G>C p.M162I (on ENST00000397770 / NM_183337.3; = p.M141I on NM_003834.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 27/67 reads (40%) | SIFT deleterious (0.04); PolyPhen benign (0.045); catalogued as COSV51453100; called by muse, mutect2, varscan2
- CFAP94 | c.980A>G p.K327R (on ENST00000320267 / NM_001352064.2; = p.K333R on NM_018272.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 48/504 reads (10%) | SIFT tolerated (0.54); PolyPhen benign (0.001); called by muse, mutect2
- LGALS14 | c.369_387del p.M123Ifs*4 | Frame Shift Del (DEL) | VAF 168/502 reads (33%) | called by mutect2, pindel, varscan2
- ORM1 | c.329-1G>A p.X110_splice | Splice Site (SNP) | VAF 51/178 reads (29%) | called by muse, varscan2
- PALM2AKAP2 | c.161T>A p.L54Q (on ENST00000374531 / NM_001037293.2; = p.L52Q on NM_007203.5) | Missense Mutation (SNP) | VAF 15/221 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.642); called by muse, mutect2
- SLC5A12 | c.1526C>A p.A509E | Missense Mutation (SNP) | VAF 22/544 reads (4%) | SIFT deleterious (0.01); PolyPhen benign (0.091); called by muse, mutect2
- DOT1L | c.2595G>T p.L865= | Silent (SNP) | VAF 3/18 reads (17%) | catalogued as rs1203031310; called by muse, mutect2
- FNDC1 | c.2946C>T p.P982= | Silent (SNP) | VAF 17/38 reads (45%) | catalogued as rs775046264, COSV51931624; called by muse, mutect2, varscan2
- GPR132 | c.345C>T p.C115= | Silent (SNP) | VAF 21/342 reads (6%) | catalogued as rs1333906981; called by muse, mutect2
- TEX13A | c.345G>A p.R115= | Silent (SNP) | VAF 14/94 reads (15%) | catalogued as COSV61146632; called by muse, mutect2, varscan2
- TLR8 | c.2394G>C p.L798= (on ENST00000218032 / NM_138636.5; = p.L816= on NM_016610.4) | Silent (SNP) | VAF 55/225 reads (24%) | catalogued as COSV54318879; called by muse, mutect2, varscan2
